Surgical pathology report (de-identified scan), TCGA case TCGA-60-2703, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2703-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Patient:

Med. Record [REDACTED]

Date of Birth: [REDACTED]

Location: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. 4R LYMPH NODE
- B. LEVEL 11 LYMPH NODE
- C. LOWER AND MIDDLE LOBE RIGHT LUNG
- D. LEVEL 7 LYMPH NODE
- E. LEVEL 10 LYMPH NODE
- F. LEVEL 4R LYMPH NODE
- G. LEVEL 2R LYMPH NODE

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

Right lung ca.

FROZEN SECTION DIAGNOSIS:

A. 4R LYMPH NODE

Negative for metastatic tumor by [REDACTED]

C. LOWER AND MIDDLE LOBE RIGHT LUNG

Bronchial margin negative for tumor by [REDACTED]

GROSS DESCRIPTION:

A. 4R LYMPH NODE

Received fresh in a single container labelled [REDACTED] and designated "4R lymph node" are three fragments of soft tan red tissue measuring in aggregate 0.5x0.3x0.1cm. Entirely submitted in one cassette labelled FSA for frozen section diagnosis.

TO:nr

B. LEVEL 11 LYMPH NODE

[REDACTED]

[page 2 of 4]
[REDACTED]

Received in formalin in a single container labelled [REDACTED] and designated "level 11 lymph node" and consists of one soft tan red lymph node measuring 2.0x1.0x0.5cm. The lymph node is bisected and the cut surfaces are smooth, dark tan red and anthracotic. The entire specimen is submitted in cassette B1.

C. LOWER AND MIDDLE LOBE RIGHT LUNG

Received fresh in a single container labelled [REDACTED] and designated "lower and middle lobe right lung" and consists of a lower lobe of lung and portion of middle lobe weighing 372gm. after fixation. The portion of middle lobe measures 7.5x6.0x2.0cm. and the lower lobe measures 16.0x14.0x5.5cm. Palpable within the lower lobe is a large mass. The bronchial resection margin is submitted en face for frozen section diagnosis in block FSC1. The pleural surface of the lung ranges from grey purple to tan red with focal areas of anthracosis. The region of pleura overlying the tumor is inked black. The portion of middle lobe has a 7.5cm. long stapled resection margin as well as an open parenchymal resection margin which is grossly unremarkable. The lower lobe contains two stapled resection margins, one measuring 6.5cm. and the other measuring 8.5cm. in length. Sectioning through the lower lobe reveals a tan yellow firm tumor with an irregular margin measuring 5.5x5.5x4.4cm. The tumor is 0.2cm. away from the nearest pleural surface and is 4.0cm. away from the bronchial resection margin. The tumor is 1.3cm. away from the shorter stapled margin and 1.5cm. away from the longer stapled margin. Representative portions of the tumor are submitted for tissue procurement and to [REDACTED] lab. Adjacent to the tumor between it and the bronchial resection margin is a 1.8cm. diameter anthracotic lymph node. Multiple anthracotic lymph nodes are also noted around the bronchial resection margin, the largest measuring 3.0cm. in greatest dimension. One of the lymph nodes adjacent to the bronchial resection margin appears grossly positive for tumor and measures 1.7cm. in greatest dimension. The bronchi are opened longitudinally within the lower lobe and in one area the tumor appears to be involving the bronchus. In another area, the tumor is surrounding a bronchus. The remainder of the cut surfaces of the lower lobe are composed of poorly aerated tan red lung parenchyma with mucus plugging. No other masses are identified. The bronchus leading into the portion of middle lobe is opened longitudinally and the bronchial mucosa is unremarkable. The portion of middle lobe is serially sectioned and the cut surfaces are composed of tan red poorly aerated lung parenchyma. No masses are identified. This portion of the lung is not involved by the tumor. Representative portions of the specimen are submitted per the code of sections.

Code of sections:

- FSC1: bronchial resection margin en face
- C2: tumor at closest approach to pleura
- C3-C4: tumor
- C5: tumor involving bronchus
- C6: tumor adjacent to bronchus
- C7: lung, lower lobe, short stapled resection margin en face
- C8: lung, lower lobe, long stapled resection margin en face
- C9-C10: lung, lower lobe, adjacent to tumor
- C11: lung, lower lobe, away from tumor
- C12: one level 12 lymph node, lower lobe
- [REDACTED]

[page 3 of 4]
[REDACTED]

C13-C14: one level 12 lymph node, lower lobe, grossly positive

C15: one level 12 lymph node, lower lobe

C16-C17: one level 12 lymph node, lower lobe

C18: one level 13 lymph node, lower lobe

C19-C20: lung, middle lobe

D. LEVEL 7 LYMPH NODE

Received in formalin in a single container labelled [REDACTED] and designated "level 7 lymph node" and consists of two soft tan lymph nodes. One measures 0.6x0.5x0.4cm. and the other measures 2.3x0.9x0.6cm. Both lymph nodes are bisected and the larger one has anthracotic cut surfaces and the smaller one has tan unremarkable cut surfaces. Both lymph nodes are submitted in cassettes D1 and D2 with one lymph node in each cassette.

E. LEVEL 10 LYMPH NODE

Received in formalin in a single container labelled [REDACTED] and designated "level 10 lymph node" are three tan black soft lymph nodes measuring 0.7x0.6x0.3cm., 0.8x0.7x0.5cm. and 1.2x1.1x0.6cm. All three lymph nodes are bisected and the cut surfaces are anthracotic. The entire specimen is submitted in cassettes E1 through E3 with one lymph node in each cassette.

F. LEVEL 4R LYMPH NODE

Received in formalin in a single container labelled [REDACTED] and designated "level 4R lymph node" and consists of two fragments of soft tan yellow fibroadipose tissue measuring 2.0x1.0x0.8cm. No definite lymph node is identified. The entire specimen is submitted in cassettes F1 and F2.

G. LEVEL 2R LYMPH NODE

Received in formalin in a single container labelled [REDACTED] and designated "level 2R lymph node" and consists of a single soft tan yellow portion of fibroadipose tissue measuring 1.0x0.8x0.3cm. No definite lymph node is identified. The entire specimen is submitted in a single cassette labelled G1.

[REDACTED]

DIAGNOSIS:

A. LYMPH NODE, LEVEL 4R, EXCISION:

-ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1)

B. LYMPH NODE, LEVEL 11, EXCISION:

-ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1)

C. LUNG, RIGHT LOWER AND MIDDLE LOBES, RESECTION:

-INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED,
(5.5X5.5X4.4CM.) OF LOWER LOBE WITH EXTENSIVE NECROSIS

-SURGICAL MARGINS NEGATIVE FOR CARCINOMA

-TWO OF FIVE PERIBRONCHIAL LYMPH NODES, POSITIVE FOR METASTATIC
CARCINOMA (2/5), SEE TEMPLATE

D. LYMPH NODE, LEVEL 7, EXCISION:

-TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2)

E. LYMPH NODE, LEVEL 10, EXCISION:

[REDACTED]

[page 4 of 4]
-
- THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3)
- F. LYMPH NODE, LEVEL 4R, EXCISION:
-ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1)
- G. LYMPH NODE, LEVEL 2R, EXCISION:
-ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1)

Lung template

1. Tumor type: Squamous cell carcinoma
2. Histologic grade: Poorly differentiated
3. Tumor location: Peripheral
4. Tumor size: 5.5x5.5x4.4cm.
5. Angiolymphatic invasion: present
6. Perineural invasion: Absent
7. Involvement of main stem bronchus: Absent
8. Bronchial margin: Negative
9. Visceral pleural margin: Negative
10. Lymph nodes: Positive (2/14)
11. In-situ carcinoma: Absent
12. Pathologic stage: pT2pN1Mx
13. Non-neoplastic lung: Mild emphysema, mucous plugging of bronchioles and alveoli, focal mild
Peribronchoalveolar chronic inflammation
-

Source: NCI Genomic Data Commons file b4729d39-554f-4cc2-a4f9-9075181dfadf (TCGA-60-2703.880FE05A-3A40-430E-8254-1A0BECDFC462.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).